Somatic mutation profile of tumor specimen 0DP2CX from CCDI case PBCDBD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.5 years (4,924 days).
Specimen 0DP2CX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e61d6c2c-7f76-4726-a648-89654c912b22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP2CG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1d24d23-e1a1-43fe-97e4-7df9b4be61db

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GIMAP1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as rs201983958; called by muse, mutect2
- KCTD2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 21/522 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2
- WDR97 | c.2275del p.L759Sfs*8 | Frame Shift Del (DEL) | VAF 66/489 reads (13%) | called by mutect2, varscan2
- CCL14 | c.183G>A p.K61= (on ENST00000618404 / NM_032963.4; = p.K77= on NM_032962.4) | Silent (SNP) | VAF 77/616 reads (13%) | called by muse, mutect2, varscan2
- GSTT4 | c.375G>A p.G125= | Silent (SNP) | VAF 69/820 reads (8%) | called by muse, mutect2
- NLRP4 | c.714C>T p.G238= | Silent (SNP) | VAF 22/518 reads (4%) | catalogued as rs915066316, COSV56711283; called by muse, mutect2
- PPRC1 | c.1962A>G p.P654= | Silent (SNP) | VAF 119/808 reads (15%) | called by muse, mutect2, varscan2
- CARD14 | c.*12C>T | 3'UTR (SNP) | VAF 174/756 reads (23%) | called by muse, mutect2, varscan2
